Gene-level copy-number profile of tumor specimen TCGA-JV-A75J-01A from TCGA case TCGA-JV-A75J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 43.8 years (16,001 days).
Specimen TCGA-JV-A75J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.2dc3c665-007d-46c5-86ff-9ac939f7eb9b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-JV-A75J-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a5ad7e48-eaf8-4f4e-8b70-de45a9138d31

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 154; copy number 1: 8,159; copy number 2: 43,704; copy number 3: 6,160; copy number 4: 772; copy number 5: 226; copy number 6: 302; copy number 7: 93; copy number 8: 27; copy number 9: 30; copy number 10: 27; copy number 12: 3; copy number 13: 111; copy number 15: 2; copy number 16: 36; copy number 19: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-JV-A75J-01A-11D-A32H-01): tumor purity 0.99, ploidy 2.02, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 154 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,700,595–9,442,380, 7 genes: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P.
- chr17:31,094,927–31,382,116, 1 gene (within-gene range 0–1): NF1.
- chr17:31,272,013–31,538,211, 10 genes: OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P, RN7SL45P, AC003101.3, MIR4724.
- chr17:46,193,576–46,196,723, 1 gene: KANSL1-AS1.
- chr21:13,095,305–20,828,622, 135 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 764 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:204,306,842–205,620,162, 7 genes, copy number 5 (within-gene range 3–5): DSTNP5, AC106901.1, AC016903.1, AC016903.2, PARD3B, AC007736.1, AC008171.1.
- chr2:209,072,597–209,147,687, 2 genes, copy number 6: HSPA8P6, CRYGFP.
- chr8:87,540,835–89,243,793, 14 genes, copy number 10: AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3, RPSAP74.
- chr8:110,899,996–111,040,372, 1 gene, copy number 19 (within-gene range 3–19): LINC01608.
- chr8:118,923,557–120,056,201, 25 genes, copy number 5–12: TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2, AP005717.2, DSCC1, AC021945.1, RN7SL396P, AP005717.1, DEPTOR, RNA5SP277, AC091563.1.
- chr8:120,913,065–129,730,445, 141 genes, copy number 8–16 (within-gene range 2–16) (broad region; genes not listed).
- chr8:139,727,725–141,518,737, 35 genes, copy number 7: TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.2, AC138647.1.
- chr8:143,829,518–144,416,844, 45 genes, copy number 5: AC234917.3, AC234917.1, NRBP2, MIR6845, AC234917.2, EPPK1, AC109322.2, PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97, HGH1, TSSK5P, MROH1, BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4.
- chr10:89,644,603–89,840,861, 9 genes, copy number 5: AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4, KIF20B, MTND5P42, LINC00865, MARK2P16.
- chr10:96,112,747–96,359,365, 8 genes, copy number 5: RNU6-271P, AC021037.1, ZNF518A, BLNK, NPM1P25, AL136181.1, DNTT, OPALIN.
- chr10:101,784,443–101,843,920, 3 genes, copy number 5 (within-gene range 2–5): OGA, KCNIP2-AS1, KCNIP2.
- chr10:101,912,998–101,913,279, 1 gene, copy number 5: Metazoa_SRP.
- chr10:128,181,032–130,537,406, 26 genes, copy number 6–15 (within-gene range 1–15): LINC01163, AL390763.1, LINC02667, AL355537.1, AL355537.2, AL391869.1, AL359508.1, MGMT, AL355531.1, AL157832.2, AL157832.1, LINC02666, EBF3, AL354950.2, MIR4297, AL354950.1, AL354950.3, C10orf143, AL139123.1, CTAGE7P, PPIAP32, GLRX3, LINC02646, AL157712.1, Y_RNA, AC016816.1.
- chr21:37,187,666–38,121,345, 12 genes, copy number 5 (within-gene range 4–5): TTC3-AS1, DSCR9, RN7SL678P, AP001432.1, VPS26C, AP001412.1, AP001437.2, AP001437.1, DYRK1A, AP001407.1, KCNJ6, KCNJ6-AS1.
- chr21:45,405,165–45,513,720, 1 gene, copy number 9 (within-gene range 2–9): COL18A1.
- chr21:45,478,266–46,665,124, 40 genes, copy number 9–13: MIR6815, SLC19A1, LINC01694, AL133493.1, AL133493.2, PCBP3, AL133492.1, PCBP3-AS1, AJ011931.2, AJ011931.1, AJ239328.1, AJ011932.1, COL6A1, AP001476.1, AP001476.3, AP001476.2, PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3, YBEY, C21orf58, PCNT, AP000471.1, RPL18AP2, DIP2A, DIP2A-IT1, RNU6-396P, S100B, PRMT2, DSTNP1.
- chr22:19,565,203–23,435,071, 290 genes, copy number 6 (broad region; genes not listed).
- chr22:23,901,432–26,676,475, 104 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
